Gene-level copy-number profile of tumor specimen TCGA-36-1571-01A from TCGA case TCGA-36-1571, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.7 years (19,608 days).
Specimen TCGA-36-1571-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.63eb62f1-969d-49a9-963a-af10e9e878cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-1571-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/428259e9-7238-44ee-9013-e297aa64b12d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,974; copy number 2: 18,353; copy number 3: 22,136; copy number 4: 9,723; copy number 5: 2,706; copy number 6: 1,667; copy number 7: 275; copy number 8: 77; copy number 9: 757; copy number 10: 492; copy number 11: 373; copy number 12: 4; copy number 13: 15; copy number 14: 214; copy number 16: 3; copy number 18: 36; copy number 32: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-1571-01): tumor purity 0.91, ploidy 3.18, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,257 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:31,506,422–32,228,543, 3 genes, copy number 7 (within-gene range 5–7): LINC02501, LINC02506, AC097654.1.
- chr6:63,719,980–65,707,226, 1 gene, copy number 9 (within-gene range 6–12): EYS.
- chr6:64,631,205–66,728,904, 8 genes, copy number 8–12: HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr6:67,456,346–68,635,161, 15 genes, copy number 13: AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1.
- chr6:71,126,893–76,092,940, 90 genes, copy number 9 (broad region; genes not listed).
- chr6:80,355,424–80,557,189, 8 genes, copy number 9: AL359715.3, RPL17P25, AL359715.4, AL359715.1, AL359715.2, RPSAP72, AL596028.1, AL590824.1.
- chr7:40,964,667–41,133,507, 2 genes, copy number 9 (within-gene range 2–9): LINC01450, LINC01449.
- chr8:135,859,369–139,127,953, 15 genes, copy number 7 (within-gene range 6–7): LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2.
- chr11:69,371,463–74,009,085, 164 genes, copy number 9–18 (broad region; genes not listed).
- chr12:66,767–45,610,620, 956 genes, copy number 9–10 (broad region; genes not listed).
- chr14:18,333,726–22,957,161, 358 genes, copy number 11–14 (broad region; genes not listed).
- chr14:22,956,950–22,957,029, 1 gene, copy number 11: MIR4707.
- chr14:25,647,304–28,823,817, 28 genes, copy number 10–32 (within-gene range 1–32): LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282.
- chr19:14,619,117–17,848,071, 180 genes, copy number 8–14 (broad region; genes not listed).
- chr19:20,033,444–20,661,596, 34 genes, copy number 10 (within-gene range 2–10): AC006539.2, AC006539.3, BNIP3P13, ZNF90, AC006539.1, AC011447.5, AC011447.3, AC011447.1, AC011447.2, BNIP3P15, ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1, BNIP3P18, AC078899.4, BNIP3P19, AC078899.5, ZNF826P, BNIP3P20, AC078899.2, MIR1270, BNIP3P22, AC008554.1, BNIP3P23, ZNF737, AC010636.2, VN1R78P, AC010636.1, ZNF626.
- chr19:20,923,222–23,031,818, 102 genes, copy number 7–10 (broad region; genes not listed).
- chr19:39,685,244–40,094,406, 20 genes, copy number 7: AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1.
- chr20:37,975,156–38,578,859, 30 genes, copy number 11 (within-gene range 4–11): RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2.
- chr20:41,684,986–48,827,999, 197 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr20:51,386,957–54,651,169, 45 genes, copy number 8 (within-gene range 2–8): NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.

Autosomal genes at a single copy (total copy number 1): 553. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
